Surgical pathology report (de-identified scan), TCGA case TCGA-77-7138, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7138-01A (Primary Tumor).

LEFT LOWER LOBE

Clinical Notes:

SCC left lower lobe lung.

Macroscopy:

Specimen is labelled "left lower lobe" and consists of a lobe of lung measuring 125 x 75 x 60 mm in the fresh state. There is a cavitated mass present within the lung measuring 70 x 55 x 40 mm with overlying thickened pleura. On sectioning, it contains thick bloodstained semi-liquid material. Surrounding the cavity, the wall is irregularly roughened and thickened by white sclerotic tissue. The surrounding lung is yellow in keeping with endogenous lipid pneumonia. It appears well clear of the bronchial resection margin. No other lesions are identified on sectioning of the lung. [RS bronchial resection margin and peribronchial lymph nodes, A; tumour and pleura, B-C; RS tumour, D-E; RS adjacent lung, F; further peribronchial lymph node, G.]

Microscopy:

Sections show a moderately differentiated keratinizing squamous cell carcinoma with extensive necrosis and cavitation. It lies well clear of the bronchial margin and does not invade the pleura, although the overlying pleura does appear fibrotic. Tumour is seen within a large pulmonary vein. Peribronchial lymph nodes show no evidence of malignancy. Adjacent lung parenchyma shows organizing obstructive pneumonitis, while distant lung parenchyma is unremarkable.

Summary:

Left lower lobe:

Squamous cell carcinoma.

1. No involvement of pleura, bronchial margin or peribronchial lymph nodes.
2. Vascular infiltration present.
3. Pathological stage T2 NO Mx.

P-01100 T-28000 M-80703

Reported by Dr [REDACTED]
Pathology Registrar/Pathologist
[REDACTED]

Further report:

Elastic stain demonstrates that there is invasion of tumour into the overlying thickened pleura. No tumour is present at the pleural surface.

Conclusion:

Squamous cell carcinoma of left lower lobe.

1. Surgical margins clear
2. No lymph node metastases
3. Vascular invasion present
4. Pleural invasion present
5. Pathological stage T2 N0 MX.

Reported by Dr [REDACTED]
Anatomical Pathologist
[REDACTED]

cc: [REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file 241cad2d-7320-4d18-96de-d1854205e3c6 (TCGA-77-7138.BAEBD9A2-9AE7-462A-B5BD-8C5C7C03BF01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).